Somatic mutation profile of tumor specimen TCGA-BR-A4IU-01A (aliquot TCGA-BR-A4IU-01A-22D-A25D-08) from TCGA case TCGA-BR-A4IU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 34.5 years (12,601 days).
Specimen TCGA-BR-A4IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd9219b8-4322-4633-bd83-0b686f61248b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4IU-10A (Blood Derived Normal), aliquot TCGA-BR-A4IU-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f432aab-fd2f-4f10-92fe-a34f96f5826c

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.526C>T p.R176W (on ENST00000545399 / NM_001256214.2; = p.R163W on NM_152296.5) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57490859; called by muse, mutect2, varscan2
- GK2 | c.1217A>G p.E406G | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62628232; called by muse, mutect2
- GRID1 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60035061, COSV60049941; called by muse, mutect2, varscan2
- HBG2 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57964478; called by muse, mutect2, varscan2
- KMT2E | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV99995566; called by mutect2, varscan2
- KRTAP5-2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV101295064; called by muse, mutect2
- NKRF | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs144370117, COSV58662345; called by muse, mutect2, varscan2
- OR2L8 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs894801430, COSV61728159; called by muse, mutect2, varscan2
- PCDHGA12 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52766191; called by muse, mutect2, varscan2
- PGR | c.2281T>A p.F761I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54809795; called by muse, mutect2, varscan2
- PLCB4 | c.2995_2996del p.E999Nfs*13 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs758685931; called by mutect2, pindel
- PRDM1 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748874731, COSV64846871; called by muse, mutect2
- RET | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356141763, COSV60707014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF19B | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.225); catalogued as rs371235809, COSV52390122; called by muse, mutect2
- RXFP1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1341578609, COSV57055878, COSV57057785; called by muse, mutect2, varscan2
- SPTA1 | c.5197T>G p.L1733V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV63749514, COSV63749741; called by muse, mutect2, varscan2
- ZNF318 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58936933; called by muse, mutect2
- CFAP61 | c.2676C>T p.A892= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55645018; called by muse, mutect2, varscan2
- FCRLA | c.957G>A p.P319= (on ENST00000367959; = p.P296= on NM_032738.4) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs754322132, COSV52688052; called by muse, mutect2, varscan2
- NRG3 | c.999G>A p.P333= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1482151759, COSV64581351; called by muse, mutect2, varscan2
- PCDHB9 | c.1899C>T p.R633= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53383217; called by muse, mutect2, varscan2
